Gene-level copy-number profile of tumor specimen TCGA-A6-6142-01A from TCGA case TCGA-A6-6142, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 56.1 years (20,485 days).
Specimen TCGA-A6-6142-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.184e6d22-26fc-4819-8515-afe26fe9562d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6142-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c45a8704-7355-4c67-8e18-cbe83bc78f4e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 6,148; copy number 3: 3,797; copy number 4: 24,838; copy number 5: 16,155; copy number 6: 2,007; copy number 7: 2,490; copy number 8: 3; copy number 10: 1,501; copy number 11: 2,199; copy number 12: 539; copy number 14: 24; copy number 30: 107.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6142-01A-11D-1770-01): tumor purity 0.45, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,370 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 10–12 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 11–30 (broad region; genes not listed).
- chr20:87,250–2,524,702, 76 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr20:2,692,874–16,053,197, 209 genes, copy number 12 (within-gene range 7–12) (broad region; genes not listed).
- chr20:15,892,355–64,313,132, 1,160 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
